Somatic mutation profile of tumor specimen TCGA-05-4417-01A (aliquot TCGA-05-4417-01A-22D-1855-08) from TCGA case TCGA-05-4417, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 51.4 years (18,780 days).
Specimen TCGA-05-4417-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f58da7c-cfb2-4021-8648-5220ca782a16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4417-10A (Blood Derived Normal), aliquot TCGA-05-4417-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21f5e156-ba30-4ced-8c5b-8276a47950b9

The open-access MAF lists 330 somatic variants for this specimen: 253 protein-altering or splice-affecting, 69 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 210, Silent 69, Nonsense Mutation 16, Splice Site 11, Frame Shift Del 9, Frame Shift Ins 4, 3'UTR 3, Splice Region 2, Intron 2, RNA 1, In Frame Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8669T>G p.L2890R | Missense Mutation (SNP) | VAF 32/74 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53724827, COSV53747216; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 15/30 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RAPSN | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121909257, CM080516, COSV100100029; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.868); catalogued as COSV50957066, COSV99031497; called by muse, mutect2
- ABCA12 | c.7626C>A p.N2542K (on ENST00000272895 / NM_173076.3; = p.N2224K on NM_015657.3) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV55948610; called by muse, mutect2, varscan2
- ABCB11 | c.2809G>C p.G937R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55584828; called by muse, mutect2, varscan2
- ABCG5 | c.1272C>A p.Y424* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV53209301; called by muse, mutect2, varscan2
- ABHD8 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV56043869, COSV56046304; called by muse, mutect2
- AC136428.1 | c.149A>C p.N50T | Missense Mutation (SNP) | VAF 50/291 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as COSV71169050; called by muse, mutect2, varscan2
- ACSL6 | c.1622T>A p.I541N (on ENST00000379240; = p.I566N on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57294133; called by muse, varscan2
- ADA2 | c.1360G>T p.D454Y (on ENST00000262607; = p.D213Y on NM_177405.3) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52830873, COSV52833424; called by muse, mutect2, varscan2
- ADAM32 | c.512T>C p.F171S | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV65947003; called by muse, mutect2, varscan2
- ADAMTS3 | c.3329G>T p.G1110V | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV54383999; called by muse, mutect2, varscan2
- ADCY6 | c.163C>G p.P55A | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.156); catalogued as COSV57166140; called by muse, mutect2, varscan2
- AGBL1 | c.1904T>C p.F635S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66848023; called by muse, mutect2, varscan2
- AGTPBP1 | c.436+1G>T p.X146_splice | Splice Site (SNP) | VAF 27/98 reads (28%) | catalogued as COSV61268306; called by muse, mutect2, varscan2
- AKT3 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 22/77 reads (29%) | catalogued as COSV99794554; called by muse, mutect2, varscan2
- AOAH | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51735280; called by muse, mutect2, varscan2
- APCS | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV99661220; called by muse, mutect2, varscan2
- APLF | c.1143T>A p.Y381* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100376469; called by muse, mutect2, varscan2
- APLF | c.1144G>T p.G382W | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100376473; called by muse, mutect2, varscan2
- APOB | c.12276C>A p.H4092Q | Missense Mutation (SNP) | VAF 36/266 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as COSV51922214; called by muse, mutect2, varscan2
- ARHGAP20 | c.1441A>C p.N481H | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52806255; called by muse, mutect2, varscan2
- ARMC1 | c.183+1G>T p.X61_splice | Splice Site (SNP) | VAF 25/125 reads (20%) | catalogued as COSV52532983; called by muse, mutect2, varscan2
- ASH1L | c.7036C>G p.Q2346E (on ENST00000368346 / NM_001366177.2; = p.Q2341E on NM_018489.3) | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.857); catalogued as COSV64205218; called by muse, mutect2
- ASPM | c.5366A>C p.K1789T | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV54124145; called by muse, mutect2, varscan2
- ATP1A4 | c.3016G>T p.V1006F | Missense Mutation (SNP) | VAF 88/372 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV63623869; called by muse, mutect2, varscan2
- ATP2B2 | c.2420C>T p.T807M (on ENST00000352432; = p.T773M on NM_001683.5) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59488459; called by mutect2, varscan2
- B3GNT6 | c.122G>T p.R41M | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0.265); catalogued as COSV100845765; called by muse, mutect2, varscan2
- BTAF1 | c.5293A>T p.M1765L | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV56429568; called by muse, mutect2, varscan2
- CABIN1 | c.3618G>T p.W1206C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54077305; called by muse, mutect2, varscan2
- CACNA1G | c.4091C>T p.S1364F | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV61719975; called by muse, mutect2, varscan2
- CACNA2D3 | c.746A>T p.Q249L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV55511607; called by muse, mutect2, varscan2
- CALCOCO1 | c.1005+1G>A p.X335_splice | Splice Site (SNP) | VAF 24/83 reads (29%) | catalogued as rs1043016769, COSV50411618; called by muse, mutect2, varscan2
- CAPN6 | c.1765T>A p.C589S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as COSV60693739; called by muse, mutect2, varscan2
- CCDC122 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV55708616, COSV99865801; called by muse, mutect2
- CD1A | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56860201; called by muse, mutect2, varscan2
- CD1E | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV63769885; called by muse, varscan2
- CD79B | c.675C>A p.H225Q | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50075975; called by muse, mutect2, varscan2
- CDX4 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV65171411; called by muse, mutect2, varscan2
- CILP | c.365G>C p.R122T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV56021705, COSV56026516; called by muse, mutect2, varscan2
- CLCA4 | c.2528T>A p.I843N | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65282104, COSV65284498; called by muse, mutect2, varscan2
- CLCN1 | c.2204C>A p.T735N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as COSV58367231; called by muse, mutect2, varscan2
- CLIC2 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58935459; called by muse, mutect2, varscan2
- COL12A1 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV100485574; called by muse, mutect2, varscan2
- COL14A1 | c.2646C>A p.N882K | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as COSV52846758; called by muse, mutect2, varscan2
- COL22A1 | c.3053T>A p.L1018Q | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV57321944; called by muse, mutect2, varscan2
- COL4A6 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57858852; called by muse, mutect2, varscan2
- COL9A1 | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57878243, COSV57881698; called by muse, mutect2, varscan2
- CROCC | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.685); catalogued as rs368304788; called by muse, mutect2, varscan2
- CSHL1 | c.346T>A p.S116T (on ENST00000309894 / NM_022581.3; = p.S22T on NM_001318.4) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV99367834; called by muse, varscan2
- CSMD3 | c.4862A>G p.N1621S (on ENST00000297405 / NM_001363185.1; = p.N1517S on NM_052900.3) | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.464); catalogued as rs1563632779, COSV52096689; called by muse, mutect2, varscan2
- CTSG | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV53534524; called by muse, mutect2, varscan2
- CXCL16 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs988845573, COSV99351086; called by muse, mutect2, varscan2
- CYP2A7 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.148); catalogued as COSV52496894; called by muse, mutect2, varscan2
- DCHS1 | c.414C>A p.D138E | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55030104, COSV55042561; called by muse, mutect2, varscan2
- DHX57 | c.1309G>T p.V437L | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1437753174, COSV54882246; called by muse, mutect2, varscan2
- DISP3 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.034); catalogued as COSV53819778, COSV53827566; called by mutect2, varscan2
- DNAI2 | c.1758G>T p.E586D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV56756658; called by muse, mutect2, varscan2
- DNTTIP2 | c.2254A>G p.K752E | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63283537; called by muse, mutect2, varscan2
- DPP10 | c.1184G>T p.R395L | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59662567; called by muse, mutect2, varscan2
- DUSP7 | c.763G>T p.G255C | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56588569, COSV56589117; called by muse, mutect2, varscan2
- DYSF | c.3334C>T p.L1112F | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50266950; called by muse, mutect2
- DYTN | c.1678C>T p.R560* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as rs1239661791, COSV71513265; called by muse, mutect2, varscan2
- DYTN | c.1237del p.D413Ifs*75 | Frame Shift Del (DEL) | VAF 16/126 reads (13%) | catalogued as COSV101510814; called by mutect2, pindel, varscan2
- EPHA5 | c.1328C>A p.A443E | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56629808; called by muse, varscan2
- F9 | c.23T>C p.M8T | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs770709443, COSV54378528; called by muse, mutect2, varscan2
- FAM135B | c.2878C>T p.P960S | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as rs1401543542, COSV52703413; called by muse, varscan2
- FAT2 | c.8553C>A p.D2851E | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as COSV55812796; called by muse, mutect2, varscan2
- FGFR3 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445397378, COSV99038037; called by muse, mutect2, varscan2
- FMR1 | c.1561G>T p.E521* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99503076; called by muse, mutect2, varscan2
- FRMPD2 | c.788+1G>T p.X263_splice | Splice Site (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100563641, COSV59717037; called by muse, mutect2, varscan2
- GABRG1 | c.114G>T p.K38N | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV54949677, COSV99777225; called by muse, mutect2, varscan2
- GALNT13 | c.1339C>A p.R447S | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.325); catalogued as COSV67209257, COSV67209418; called by muse, mutect2, varscan2
- GFRAL | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV61228626; called by muse, mutect2, varscan2
- GLDC | c.1750C>A p.P584T | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58676174; called by muse, mutect2, varscan2
- GPR101 | c.1041C>A p.D347E | Missense Mutation (SNP) | VAF 46/312 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as COSV99981300; called by muse, mutect2, varscan2
- GPRC6A | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 20/89 reads (22%) | catalogued as rs761917013, COSV59951439; called by muse, mutect2, varscan2
- GRK5 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64865507; called by muse, mutect2, varscan2
- GSTO2 | c.467A>T p.E156V | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100086632; called by muse, mutect2
- GYPC | c.109C>A p.P37T | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99391631; called by muse, mutect2, varscan2
- HAS2 | c.771T>G p.S257R | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58261810; called by muse, mutect2, varscan2
- HAUS7 | c.692A>T p.Q231L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV100444034; called by muse, mutect2, varscan2
- HECTD1 | c.1867A>G p.K623E | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV67944973; called by muse, mutect2, varscan2
- HECTD3 | c.2171A>T p.K724M | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV64669622; called by muse, mutect2, varscan2
- HRNR | c.1461C>A p.H487Q | Missense Mutation (SNP) | VAF 130/473 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64253890; called by muse, mutect2, varscan2
- HS3ST4 | c.881C>A p.A294D | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100500472; called by muse, mutect2, varscan2
- IFNB1 | c.368T>C p.L123P | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101207780; called by muse, mutect2, varscan2
- IGSF9B | c.1083G>C p.K361N | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58063688; called by muse, mutect2, varscan2
- IL15 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56724087; called by muse, mutect2, varscan2
- IL20RA | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.425); catalogued as COSV57356251; called by muse, mutect2, varscan2
- INCENP | c.1900G>T p.E634* (on ENST00000394818 / NM_001040694.2; = p.E630* on NM_020238.3) | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV53913057; called by muse, mutect2, varscan2
- INSYN1 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101138703; called by muse, mutect2, varscan2
- ITGAV | c.1949G>T p.G650V | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53708964; called by muse, mutect2, varscan2
- ITIH6 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV54486235; called by muse, mutect2, varscan2
- KCNJ3 | c.1290G>T p.L430F | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV54530895; called by muse, mutect2, varscan2
- KCTD3 | c.98G>T p.R33I | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV52063986; called by muse, mutect2, varscan2
- KIF6 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV54665941; called by muse, mutect2, varscan2
- KIN | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 91/334 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as COSV65429921; called by muse, mutect2, varscan2
- KLHL1 | c.1880G>C p.W627S | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64766543; called by muse, mutect2, varscan2
- KLHL25 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV100563482, COSV100563692; called by muse, varscan2
- LAMA2 | c.247T>G p.C83G | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70337662; called by muse, mutect2, varscan2
- LARP4 | c.804+1G>T p.X268_splice | Splice Site (SNP) | VAF 17/106 reads (16%) | catalogued as COSV53319751; called by muse, mutect2, varscan2
- LCT | c.2080G>T p.A694S | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.022); catalogued as COSV51543757, COSV51545227; called by muse, mutect2, varscan2
- LMAN2 | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs767386223, COSV57423716, COSV57425234; called by muse, mutect2, varscan2
- LONRF3 | c.1072C>A p.L358I (on ENST00000371628 / NM_001031855.3; = p.L317I on NM_024778.5) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV59149556; called by muse, mutect2, varscan2
- LPA | c.4772C>T p.T1591I | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs768994342, COSV60296126; called by muse, mutect2, varscan2
- LRRC6 | c.1247T>C p.L416P | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs865800683, COSV51537521; called by muse, mutect2, varscan2
- LRRIQ1 | c.4255C>A p.L1419I | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as COSV67825484; called by muse, mutect2, varscan2
- LUC7L | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.253); catalogued as COSV53456700; called by muse, mutect2, varscan2
- LUZP2 | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as rs775537645, COSV61194660; called by muse, mutect2, varscan2
- MFN1 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV54937846; called by muse, mutect2, varscan2
- MMP16 | c.1772G>T p.G591V | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54149863; called by muse, mutect2, varscan2
- MMP25 | c.684T>G p.F228L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV100339373; called by muse, mutect2, varscan2
- MROH2B | c.3399C>G p.I1133M | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.269); catalogued as COSV68180811, COSV68181224; called by muse, mutect2, varscan2
- MROH2B | c.2474A>T p.H825L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.036); catalogued as COSV68180815; called by muse, mutect2, varscan2
- MSH2 | c.1509T>C p.L503= | Splice Region (SNP) | VAF 27/114 reads (24%) | catalogued as COSV51875505; called by muse, mutect2, varscan2
- MTMR8 | c.1524G>T p.Q508H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66392242; called by muse, mutect2, varscan2
- MTNR1A | c.207A>C p.L69F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56154866; called by muse, mutect2, varscan2
- MUC16 | c.17234C>A p.A5745D | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.654); catalogued as rs752992011, COSV67442904; called by muse, mutect2, varscan2
- MUC16 | c.1757C>A p.S586Y | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as COSV67442918; called by muse, mutect2, varscan2
- MUC5B | c.14534C>A p.T4845N | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs753810214, COSV71589910; called by muse, mutect2
- MUC5B | c.14536T>C p.W4846R | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV71589911; called by muse, mutect2
- MXI1 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99491268; called by muse, mutect2, varscan2
- MXRA5 | c.7988G>C p.G2663A | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV54223035; called by muse, mutect2, varscan2
- MXRA5 | c.1121A>G p.Y374C | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1241489893, COSV54223057; called by muse, mutect2, varscan2
- MYH15 | c.5539G>T p.E1847* | Nonsense Mutation (SNP) | VAF 46/170 reads (27%) | catalogued as COSV56303999; called by muse, mutect2, varscan2
- MYPN | c.1289C>G p.P430R | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62731416; called by muse, mutect2, varscan2
- NLRP12 | c.629C>G p.P210R | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60743336, COSV60749442; called by muse, mutect2, varscan2
- NOTCH3 | c.2452G>T p.A818S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54627056, COSV99656317; called by muse, mutect2, varscan2
- NPAP1 | c.592G>T p.V198L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61504101; called by muse, mutect2, varscan2
- NPM1 | c.412A>G p.I138V | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs747866671, COSV51544313; called by muse, mutect2, varscan2
- NRXN3 | c.672C>A p.F224L (on ENST00000557594 / NM_001272020.2; = p.F856L on NM_004796.6) | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV55313528; called by muse, mutect2, varscan2
- OR10X1 | c.892C>A p.L298I | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63766873; called by muse, mutect2, varscan2
- OR2T12 | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV58775959, COSV58779902; called by muse, mutect2, varscan2
- OR2T3 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); catalogued as rs1337766358, COSV62081681; called by muse, mutect2, varscan2
- OR4C12 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as COSV58859337, COSV58861087; called by muse, mutect2, varscan2
- OR4C46 | c.335T>A p.L112Q | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100060788, COSV60218272; called by muse, mutect2, varscan2
- OR4N2 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 83/419 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1462897309, COSV60049847, COSV60052231; called by muse, mutect2, varscan2
- OR4P4 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 55/86 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as COSV58920509, COSV58921743; called by muse, mutect2, varscan2
- OR5H6 | c.842C>T p.P281L (on ENST00000642105; = p.P265L on NM_001005479.2) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs200721570, COSV67350961; called by muse, varscan2
- OR5M3 | c.747C>A p.F249L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56565639; called by muse, mutect2, varscan2
- OR9K2 | c.490C>G p.R164G (on ENST00000305377; = p.R142G on NM_001005243.1) | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV59531307; called by muse, mutect2, varscan2
- OTOGL | c.1328G>T p.C443F (on ENST00000547103; = p.C434F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101509045; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1511G>C p.G504A (on ENST00000259318 / NM_001136562.3; = p.G735A on NM_007203.5) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV52172891; called by muse, mutect2, varscan2
- PAPPA2 | c.5350del p.D1784Tfs*23 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | catalogued as COSV62799303; called by mutect2, pindel, varscan2
- PCDH1 | c.628G>T p.G210W | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54610689; called by muse, mutect2, varscan2
- PCDHB4 | c.1777G>T p.G593C | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV52019372; called by muse, mutect2, varscan2
- PCDHB9 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as rs1554282848, COSV53375004; called by muse, mutect2, varscan2
- PCDHGB1 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.298); catalogued as rs956940005, COSV53894934; called by muse, mutect2, varscan2
- PCLO | c.5044G>T p.A1682S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV61614571; called by muse, mutect2, varscan2
- PCNT | c.2243A>T p.K748I | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV64024780; called by muse, mutect2, varscan2
- PDILT | c.181C>A p.R61S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.578); catalogued as COSV56699363; called by muse, mutect2, varscan2
- PHACTR3 | c.1138C>A p.Q380K | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.244); catalogued as COSV63025043; called by muse, mutect2, varscan2
- PIAS2 | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.109); catalogued as COSV61342027; called by muse, mutect2
- PIK3CG | c.2275G>A p.V759I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs765080806, COSV63245292; called by muse, mutect2, varscan2
- PKD2 | c.2803C>A p.L935I | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.259); catalogued as COSV52936357; called by muse, mutect2
- PLCB1 | c.2438C>G p.P813R | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV62037150; called by muse, mutect2, varscan2
- PLCB3 | c.1213C>G p.P405A | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs778667804, COSV54185598; called by muse, mutect2, varscan2
- PLCH1 | c.4712C>A p.P1571H (on ENST00000340059 / NM_001130960.2; = p.P1563H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58185444; called by muse, mutect2, varscan2
- POTEH | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 95/800 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as COSV58879567; called by muse, varscan2
- PPARD | c.1106G>T p.R369L | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV61098596, COSV61099795; called by mutect2, varscan2
- PPT2 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 37/273 reads (14%) | catalogued as COSV61353828; called by muse, mutect2, varscan2
- PRDM9 | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV57002080; called by muse, mutect2, varscan2
- PRKCI | c.223G>T p.G75* | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | catalogued as rs1478749679, COSV55516515; called by muse, mutect2, varscan2
- PTGS1 | c.1259C>A p.A420D | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.069); catalogued as rs1477059027, COSV56290012; called by muse, mutect2, varscan2
- PTPRN2 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV101233962; called by muse, mutect2, varscan2
- PTPRN2 | c.1435G>T p.G479W | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV101233965; called by muse, mutect2, varscan2
- PTPRT | c.2770+1G>T p.X924_splice | Splice Site (SNP) | VAF 36/185 reads (19%) | catalogued as COSV61958764; called by muse, mutect2, varscan2
- RBM19 | c.1963G>T p.E655* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | catalogued as COSV55687760; called by muse, mutect2, varscan2
- REG1B | c.214C>A p.L72M | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59304275; called by muse, mutect2, varscan2
- RGS22 | c.2812T>C p.W938R | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.496); catalogued as COSV62656988, COSV62657161; called by muse, mutect2, varscan2
- RGS22 | c.1689+1G>T p.X563_splice | Splice Site (SNP) | VAF 73/203 reads (36%) | catalogued as rs754546877, COSV100693074; called by muse, mutect2, varscan2
- RGS22 | c.1689G>T p.Q563H | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.288); catalogued as COSV100693075; called by muse, mutect2, varscan2
- RNF17 | c.2158G>C p.E720Q | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.419); catalogued as COSV55033492; called by muse, mutect2, varscan2
- RPH3A | c.913G>A p.G305R (on ENST00000389385 / NM_001143854.2; = p.G301R on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as COSV66989916; called by muse, mutect2, varscan2
- RPS6KA5 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100002320; called by mutect2, varscan2
- RTL8B | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV101195560; called by muse, mutect2, varscan2
- RTL9 | c.1373C>A p.T458K | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.73); catalogued as COSV101511648; called by muse, mutect2, varscan2
- RTP5 | c.1612G>T p.A538S | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV58318851; called by muse, mutect2, varscan2
- RUNX1T1 | c.1297C>A p.L433I (on ENST00000265814 / NM_001198628.1; = p.L406I on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.368); catalogued as COSV56136755, COSV56140463, COSV56153085; called by muse, mutect2, varscan2
- SAMD3 | c.383+1G>T p.X128_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100148152; called by muse, mutect2
- SAMD3 | c.383G>T p.R128I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100148153; called by muse, mutect2
- SEMA3D | c.589+1G>C p.X197_splice | Splice Site (SNP) | VAF 7/61 reads (11%) | catalogued as COSV52386881; called by muse, mutect2, varscan2
- SERPINB13 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54027266, COSV54028388; called by muse, mutect2, varscan2
- SERPINB4 | c.959G>A p.S320N | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.059); catalogued as rs770002031, COSV61984046; called by muse, mutect2, varscan2
- SF3A1 | c.1465G>T p.G489C | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53167105, COSV53167507; called by muse, mutect2, varscan2
- SGMS1 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 40/130 reads (31%) | catalogued as COSV62369069, COSV62370553; called by muse, mutect2, varscan2
- SI | c.4915G>T p.V1639L | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV52265170; called by muse, mutect2, varscan2
- SLC17A5 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.098); catalogued as rs927085655, COSV63286989; called by muse, mutect2, varscan2
- SLCO1B1 | c.1360G>T p.V454L | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV57006867; called by muse, mutect2
- SLITRK1 | c.1741C>A p.L581M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.358); catalogued as COSV65674069; called by muse, mutect2, varscan2
- SLITRK2 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.996); catalogued as COSV59422760; called by muse, mutect2, varscan2
- SLITRK5 | c.2437C>A p.L813M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.147); catalogued as rs764865341, COSV61520656; called by muse, mutect2, varscan2
- SMYD1 | c.1153T>A p.Y385N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70224354; called by muse, mutect2
- SNAP25 | c.559T>A p.S187T | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.131); catalogued as COSV54770198; called by muse, mutect2, varscan2
- SPTA1 | c.7099G>T p.G2367C | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV63748534; called by muse, mutect2, varscan2
- SPTA1 | c.2642T>C p.M881T | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV63748537; called by muse, mutect2
- SSTR4 | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.01); catalogued as COSV54796776, COSV54797912, COSV99658514; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.724T>G p.Y242D | Missense Mutation (SNP) | VAF 31/180 reads (17%) | PolyPhen possibly damaging (0.714); catalogued as COSV60319908; called by muse, mutect2, varscan2
- STK11 | c.503A>G p.H168R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58820092, COSV58821510; called by muse, mutect2
- SVEP1 | c.6088G>C p.A2030P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV104400760, COSV52835208; called by muse, mutect2, varscan2
- SYNPO2 | c.1555A>T p.S519C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.315); catalogued as COSV61105983; called by muse, mutect2, varscan2
- TCERG1L | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as COSV64046225, COSV64047850; called by muse, mutect2
- TDO2 | c.611T>A p.L204* | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as COSV72483872; called by muse, mutect2, varscan2
- TENM4 | c.5440C>A p.R1814S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53613100; called by muse, mutect2
- TEX11 | c.329C>A p.A110D (on ENST00000344304; = p.A95D on NM_031276.3) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV60225917; called by muse, mutect2, varscan2
- TFAP2A | c.43G>T p.D15Y | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100116674; called by muse, mutect2, varscan2
- TFAP2A | c.42G>C p.E14D | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs972628376, COSV100116676; called by muse, mutect2, varscan2
- THAP6 | c.422G>T p.S141I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.986); catalogued as COSV61161779; called by muse, mutect2, varscan2
- THUMPD1 | c.767A>C p.Y256S | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67262956; called by muse, mutect2, varscan2
- TNN | c.2311G>T p.V771L | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.457); catalogued as COSV53421259; called by muse, mutect2, varscan2
- TPO | c.1896C>G p.I632M | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774910439, COSV61093921; called by muse, mutect2, varscan2
- TPP1 | c.964A>G p.T322A | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV54993368; called by muse, mutect2, varscan2
- TRHDE | c.2187-1G>T p.X729_splice | Splice Site (SNP) | VAF 28/122 reads (23%) | catalogued as COSV53831560; called by muse, mutect2, varscan2
- TRPC4 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV58989657; called by muse, mutect2, varscan2
- TRPM8 | c.3239A>T p.H1080L | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV61220454; called by muse, mutect2
- TSACC | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV100966232, COSV64086354; called by muse, mutect2, varscan2
- TSHZ3 | c.2030G>T p.G677V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs1164252025, COSV53663731; called by muse, mutect2, varscan2
- TTI1 | c.2344G>T p.E782* | Nonsense Mutation (SNP) | VAF 20/115 reads (17%) | catalogued as COSV100989599, COSV65062693; called by muse, mutect2, varscan2
- TTN | c.99124C>A p.L33042I (on ENST00000591111; = p.L25618I on NM_003319.4) | Missense Mutation (SNP) | VAF 27/209 reads (13%) | PolyPhen probably damaging (0.921); catalogued as COSV59873571, COSV60091279; called by muse, mutect2, varscan2
- TTN | c.42433G>T p.G14145* (on ENST00000591111; = p.G6721* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 12/133 reads (9%) | catalogued as COSV59873610; called by muse, mutect2
- TTN | c.29282T>C p.I9761T (on ENST00000591111; = p.I8834T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | PolyPhen probably damaging (0.943); catalogued as COSV59873646; called by muse, mutect2, varscan2
- TTN | c.2630C>A p.P877H (on ENST00000591111; = p.P831H on NM_003319.4) | Missense Mutation (SNP) | VAF 8/106 reads (8%) | PolyPhen possibly damaging (0.634); catalogued as COSV100600403; called by muse, mutect2
- TUBB1 | c.889C>A p.R297S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV53885751; called by mutect2, varscan2
- UCP1 | c.807G>A p.K269= | Splice Region (SNP) | VAF 19/90 reads (21%) | catalogued as COSV53767260; called by muse, mutect2, varscan2
- VNN3 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious, low confidence (0); catalogued as rs1205750144, COSV99258116; called by muse, mutect2, varscan2
- WDPCP | c.2097G>C p.R699S | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV55412510; called by muse, mutect2, varscan2
- WNT3A | c.362C>A p.A121D | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52728274, COSV99470195; called by muse, mutect2, varscan2
- ZDHHC15 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.676); catalogued as COSV64900520; called by muse, mutect2, varscan2
- ZNF114 | c.297C>A p.H99Q | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as COSV59943494; called by muse, mutect2, varscan2
- ZNF37A | c.16-2A>G p.X6_splice | Splice Site (SNP) | VAF 32/179 reads (18%) | catalogued as COSV61072387; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.316A>T p.T106S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.099); catalogued as COSV58672377, COSV58672727; called by muse, mutect2
- ZNF621 | c.300G>T p.K100N | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV59457316; called by muse, mutect2, varscan2
- ZNF676 | c.1854G>T p.E618D (on ENST00000650058; = p.E586D on NM_001001411.3) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs543467184, COSV68092088, COSV68094567; called by mutect2, varscan2
- ZNF831 | c.2540C>A p.P847H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.843); catalogued as COSV64037095; called by muse, mutect2, varscan2
- ZNF835 | c.1342T>A p.C448S | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449260344, COSV73379151; called by muse, mutect2, varscan2
- C2CD3 | c.804_841del p.E268Dfs*8 | Frame Shift Del (DEL) | VAF 38/106 reads (36%) | called by mutect2, pindel
- C2orf16 | c.38dup p.N13Kfs*23 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- CNNM2 | c.2068del p.L690Cfs*14 | Frame Shift Del (DEL) | VAF 48/174 reads (28%) | called by mutect2, pindel, varscan2
- CSNK1G1 | c.990del p.R331Dfs*7 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by pindel, varscan2
- FOXD4L5 | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); called by mutect2, varscan2
- GAST | c.142del p.E48Sfs*? | Frame Shift Del (DEL) | VAF 30/110 reads (27%) | called by mutect2, pindel, varscan2
- GDF10 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, varscan2
- ITGB4 | c.3717_3724del p.S1239Rfs*4 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | called by mutect2, pindel, varscan2
- KL | c.2352dup p.L785Sfs*7 | Frame Shift Ins (INS) | VAF 23/71 reads (32%) | called by mutect2, pindel, varscan2
- MTPAP | c.1344dup p.G449Wfs*7 | Frame Shift Ins (INS) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- NCKAP1 | c.949_951dup p.Y317dup | In Frame Ins (INS) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- PCDH19 | c.3102_3104delinsTT p.K1034Nfs*8 (on ENST00000373034 / NM_001184880.2; = p.K986Nfs*8 on NM_020766.3) | Frame Shift Del (DEL) | VAF 19/45 reads (42%) | called by pindel, varscan2*
- SCN7A | c.782del p.G261Afs*3 | Frame Shift Del (DEL) | VAF 14/121 reads (12%) | called by mutect2, pindel, varscan2
- SFMBT1 | c.1753dup p.A585Gfs*4 | Frame Shift Ins (INS) | VAF 13/85 reads (15%) | called by mutect2, pindel, varscan2
- TRAV10 | c.98T>A p.I33N | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TRIM36 | c.457A>G p.T153A | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ABCA9 | c.4188C>T p.D1396= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as rs552343216, COSV60619980; called by muse, mutect2, varscan2
- ADCK1 | c.1512G>T p.G504= | Silent (SNP) | VAF 44/137 reads (32%) | catalogued as COSV99451222; called by muse, mutect2, varscan2
- ADCY8 | c.1317C>A p.L439= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV53895475, COSV53896845; called by muse, mutect2, varscan2
- AHSP | c.114G>C p.V38= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV56528545, COSV56529192; called by muse, mutect2, varscan2
- ALMS1 | c.3726A>T p.T1242= | Silent (SNP) | VAF 59/175 reads (34%) | catalogued as COSV52501996; called by muse, mutect2, varscan2
- BLZF1 | c.304C>T p.L102= | Silent (SNP) | VAF 32/131 reads (24%) | catalogued as rs200267284, COSV61392640; called by muse, mutect2, varscan2
- BOC | c.135C>T p.T45= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs777570698, COSV56346805; called by muse, mutect2, varscan2
- CARD11 | c.2427G>A p.Q809= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV62753917; called by muse, mutect2, varscan2
- CD1E | c.132C>A p.S44= | Silent (SNP) | VAF 33/152 reads (22%) | catalogued as COSV63769889; called by muse, varscan2
- CDH22 | c.1506C>T p.P502= | Silent (SNP) | VAF 25/144 reads (17%) | catalogued as COSV100952916, COSV64836424; called by muse, mutect2, varscan2
- CNTNAP5 | c.3057C>A p.T1019= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV70471122; called by muse, mutect2, varscan2
- COL7A1 | c.8310G>T p.R2770= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as COSV56475960; called by muse, mutect2, varscan2
- CPS1 | c.3426A>T p.V1142= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV51801292; called by muse, mutect2, varscan2
- CSMD2 | c.5853C>T p.P1951= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as rs200149093, COSV53876489; called by muse, mutect2, varscan2
- DENND1A | c.1287T>G p.T429= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as rs1417703031, COSV65322115; called by muse, mutect2
- DNAAF3 | c.933A>G p.Q311= (on ENST00000524407 / NM_001256715.2; = p.Q358= on NM_178837.4) | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV61275136; called by muse, mutect2
- DPP3 | c.742C>A p.R248= | Silent (SNP) | VAF 31/127 reads (24%) | catalogued as COSV64755803; called by muse, mutect2, varscan2
- DRAXIN | c.621C>G p.P207= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV53841585; called by muse, mutect2, varscan2
- DRD5 | c.897G>A p.S299= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs2227844; called by muse, mutect2, varscan2
- DYNC1I1 | c.462C>T p.T154= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as COSV61455296; called by muse, mutect2, varscan2
- ELOVL4 | c.828A>G p.P276= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV63953270; called by muse, mutect2, varscan2
- FAM135B | c.628T>C p.L210= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs1451908736, COSV52703427, COSV52706446; called by muse, mutect2, varscan2
- FGF5 | c.291C>A p.I97= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV56888978; called by muse, mutect2, varscan2
- GHSR | c.438C>T p.C146= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as rs1335166183, COSV99576779; called by muse, mutect2
- GRIN2A | c.1629C>T p.T543= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs758378272, COSV100409723, COSV58019096; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- KIAA0753 | c.996G>T p.R332= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV63816689; called by muse, mutect2, varscan2
- LILRB2 | c.1173G>T p.A391= | Silent (SNP) | VAF 39/198 reads (20%) | catalogued as COSV58743379; called by muse, mutect2, varscan2
- LIPI | c.168T>C p.D56= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as COSV60707715; called by muse, mutect2, varscan2
- LRRC4C | c.591C>G p.S197= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV53417555; called by muse, mutect2, varscan2
- LRRTM4 | c.945C>T p.C315= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV69138839; called by muse, varscan2
- MAGEA8 | c.549C>A p.T183= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs781914009, COSV99674466; called by muse, mutect2, varscan2
- MUC16 | c.41169G>T p.L13723= | Silent (SNP) | VAF 29/140 reads (21%) | catalogued as COSV66689637; called by muse, mutect2, varscan2
- MYO19 | c.1176A>G p.V392= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs1444003184; called by muse, mutect2, varscan2
- NCOR2 | c.5035C>T p.L1679= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV62292795; called by muse, mutect2, varscan2
- NELL1 | c.828T>C p.S276= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV54237176; called by muse, mutect2, varscan2
- NF1 | c.6264G>C p.L2088= (on ENST00000358273 / NM_001042492.3; = p.L2067= on NM_000267.3) | Silent (SNP) | VAF 27/164 reads (16%) | catalogued as rs762751192, COSV62192223, COSV62194325, COSV62222754; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPY5R | c.306C>A p.V102= | Silent (SNP) | VAF 82/261 reads (31%) | catalogued as COSV58450894; called by muse, mutect2, varscan2
- OR8J3 | c.711C>A p.A237= | Silent (SNP) | VAF 43/172 reads (25%) | catalogued as COSV56879255; called by muse, mutect2, varscan2
- OR8J3 | c.303G>T p.L101= | Silent (SNP) | VAF 65/184 reads (35%) | catalogued as rs768683469, COSV56879263; called by muse, mutect2, varscan2
- PABPC5 | c.672A>T p.P224= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV57039033; called by muse, mutect2, varscan2
- PCDHA5 | c.1752G>A p.V584= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV100972177; called by muse, mutect2, varscan2
- PCDHB13 | c.699C>A p.V233= | Silent (SNP) | VAF 36/198 reads (18%) | catalogued as COSV53392842, COSV99507237; called by muse, mutect2, varscan2
- PCDHGA6 | c.2256C>A p.T752= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV53894955; called by muse, mutect2, varscan2
- PCYT1A | c.54G>C p.A18= | Silent (SNP) | VAF 102/290 reads (35%) | catalogued as COSV53055859, COSV53058192; called by muse, mutect2, varscan2
- PSAP | c.1047G>T p.L349= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV56446729; called by muse, mutect2, varscan2
- PSG1 | c.291A>T p.G97= | Silent (SNP) | VAF 88/594 reads (15%) | catalogued as COSV54944039; called by muse, mutect2, varscan2
- PTPRD | c.1716G>C p.L572= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as COSV61926607; called by muse, mutect2, varscan2
- PXDNL | c.4332A>T p.G1444= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV62477222; called by muse, mutect2, varscan2
- QRFPR | c.1198T>C p.L400= | Silent (SNP) | VAF 44/236 reads (19%) | catalogued as COSV57675033; called by muse, mutect2, varscan2
- RGS18 | c.525T>A p.A175= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV66507049; called by muse, mutect2, varscan2
- RNF31 | c.853C>T p.L285= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV53758336; called by muse, mutect2, varscan2
- RTL9 | c.2598A>T p.P866= | Silent (SNP) | VAF 72/256 reads (28%) | catalogued as COSV101511649, COSV101511822; called by muse, mutect2, varscan2
- RYR2 | c.4872T>A p.P1624= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV63659307; called by muse, mutect2, varscan2
- SLC15A1 | c.1980T>C p.C660= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV64729823, COSV64731346; called by muse, mutect2
- SMOX | c.1602G>C p.L534= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99602960; called by muse, mutect2, varscan2
- SPRY3 | c.129C>G p.S43= | Silent (SNP) | VAF 29/133 reads (22%) | catalogued as rs755529775, COSV57141772; called by muse, mutect2, varscan2
- SYNE1 | c.15163C>T p.L5055= (on ENST00000367255 / NM_182961.4; = p.L4984= on NM_033071.3) | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV54900605; called by muse, mutect2, varscan2
- TAAR8 | c.513C>T p.V171= | Silent (SNP) | VAF 34/271 reads (13%) | catalogued as COSV51585544; called by muse, mutect2, varscan2
- TDG | c.1086G>A p.G362= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as rs1477293882, COSV57164887; called by muse, mutect2, varscan2
- TGM6 | c.1977C>G p.T659= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs1221931731, COSV52477205; called by muse, mutect2, varscan2
- TIAF1 | c.135G>A p.E45= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs1401355205, COSV100572014; called by muse, mutect2, varscan2
- TTC17 | c.2079G>A p.L693= | Silent (SNP) | VAF 30/220 reads (14%) | catalogued as COSV50005828; called by muse, mutect2, varscan2
- TTN | c.2631C>A p.P877= (on ENST00000591111; = p.P831= on NM_003319.4) | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV100600400; called by muse, mutect2
- USH2A | c.3591C>A p.S1197= | Silent (SNP) | VAF 30/158 reads (19%) | catalogued as COSV56324693, COSV56433204; called by muse, mutect2, varscan2
- ZFHX3 | c.2790G>C p.L930= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV51707254; called by muse, mutect2, varscan2
- ZNF135 | c.189C>A p.I63= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV57879984; called by muse, mutect2, varscan2
- ZNF536 | c.249C>A p.L83= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV62817841; called by muse, mutect2, varscan2
- ZNF608 | c.3846C>T p.P1282= | Silent (SNP) | VAF 42/255 reads (16%) | catalogued as COSV60435116; called by muse, mutect2, varscan2
- ZNHIT1 | c.138G>T p.A46= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs757463641, COSV59312447; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500917 T>C | 5'Flank (SNP) | VAF 20/76 reads (26%) | called by muse, varscan2
- CPLANE1 | c.*4190T>C | 3'UTR (SNP) | VAF 25/80 reads (31%) | catalogued as COSV57051167; called by muse, mutect2, varscan2
- CTAG2 | c.*55C>A | 3'UTR (SNP) | VAF 10/83 reads (12%) | catalogued as COSV99908833; called by muse, mutect2, varscan2
- DCAF12L1 | c.-2C>T | 5'UTR (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100948150; called by muse, mutect2, varscan2
- OR2W5 | n.565G>T | RNA (SNP) | VAF 34/92 reads (37%) | called by muse, mutect2, varscan2
- RBPMS | c.528+4918G>T | Intron (SNP) | VAF 22/98 reads (22%) | catalogued as COSV99823716; called by muse, mutect2, varscan2
- TENM2 | c.503-120859G>T | Intron (SNP) | VAF 40/276 reads (14%) | catalogued as COSV101585462; called by muse, mutect2, varscan2
- ZNF99 | c.*605C>A | 3'UTR (SNP) | VAF 12/74 reads (16%) | catalogued as COSV68054645; called by muse, varscan2
